Somatic mutation profile of tumor specimen TCGA-AN-A0XP-01A (aliquot TCGA-AN-A0XP-01A-11D-A117-09) from TCGA case TCGA-AN-A0XP, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 69.3 years (25,305 days).
Specimen TCGA-AN-A0XP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 596c7aaf-4119-4b2f-8207-20531e0db945.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AN-A0XP-10A (Blood Derived Normal), aliquot TCGA-AN-A0XP-10A-01D-A10G-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/14181b20-45f0-4ffc-be95-f7498eebfdf0

The open-access MAF lists 31 somatic variants for this specimen: 24 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 16, Silent 7, Splice Site 3, Frame Shift Del 3, Nonsense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 51/114 reads (45%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ADGRL2 | c.4093T>C p.S1365P (on ENST00000370717 / NM_001366005.1; = p.S1309P on NM_012302.4) | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.123); catalogued as COSV99590087; called by muse, mutect2, varscan2
- APPL2 | c.1719G>C p.K573N | Missense Mutation (SNP) | VAF 69/155 reads (45%) | SIFT tolerated (0.28); PolyPhen benign (0.373); catalogued as COSV51588037, COSV51589445; called by muse, mutect2, varscan2
- CAPN1 | c.491T>C p.V164A | Missense Mutation (SNP) | VAF 33/113 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.435); catalogued as COSV54200932; called by muse, mutect2, varscan2
- CD2 | c.742G>T p.E248* | Nonsense Mutation (SNP) | VAF 6/50 reads (12%) | catalogued as COSV65644728; called by muse, mutect2, varscan2
- CHD1L | c.178C>T p.R60C | Missense Mutation (SNP) | VAF 72/319 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs782045573, COSV63615090; called by muse, mutect2, varscan2
- CSNK1A1L | c.874T>C p.Y292H | Missense Mutation (SNP) | VAF 96/325 reads (30%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.101); catalogued as rs762010655, COSV65790049; called by muse, mutect2, varscan2
- CYP24A1 | c.449+2T>A p.X150_splice | Splice Site (SNP) | VAF 23/105 reads (22%) | catalogued as COSV53776182; called by muse, mutect2, varscan2
- DOK5 | c.525A>T p.K175N | Missense Mutation (SNP) | VAF 23/320 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.791); catalogued as COSV99374291; called by muse, mutect2
- FAT1 | c.11473C>T p.Q3825* | Nonsense Mutation (SNP) | VAF 18/33 reads (55%) | catalogued as COSV71671652; called by muse, mutect2, varscan2
- GTF2IRD2 | c.641A>G p.N214S | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1377553124, COSV63100765; called by mutect2, varscan2
- ICE1 | c.761G>A p.G254D | Missense Mutation (SNP) | VAF 37/104 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as rs780119606, COSV56830480; called by muse, mutect2, varscan2
- KRTAP13-4 | c.143A>G p.Y48C | Missense Mutation (SNP) | VAF 33/114 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.04); catalogued as rs374623376; called by muse, mutect2, varscan2
- LBR | c.1510G>A p.A504T | Missense Mutation (SNP) | VAF 45/232 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs987262840, COSV55291084; called by muse, mutect2, varscan2
- OR4K14 | c.368G>C p.R123T | Missense Mutation (SNP) | VAF 34/115 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100520450, COSV59293961; called by muse, mutect2, varscan2
- SCN8A | c.1825G>A p.E609K | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.354); catalogued as rs1355458422, COSV61990514; called by muse, mutect2, varscan2
- SH3BP1 | c.147C>G p.I49M | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.541); catalogued as COSV60929388; called by muse, mutect2, varscan2
- SLC1A4 | c.1034+2T>C p.X345_splice | Splice Site (SNP) | VAF 41/99 reads (41%) | catalogued as COSV52235679; called by muse, mutect2, varscan2
- SNRNP200 | c.2692C>T p.P898S | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as COSV60493431; called by muse, mutect2, varscan2
- TACC1 | c.1640C>T p.A547V | Missense Mutation (SNP) | VAF 61/173 reads (35%) | SIFT tolerated (0.22); PolyPhen benign (0.091); catalogued as rs758999833, COSV52527704; called by muse, mutect2, varscan2
- USP15 | c.1845-2A>C p.X615_splice (on ENST00000280377 / NM_001351159.2; = p.X586_splice on NM_006313.3 and 5 other RefSeq transcripts) | Splice Site (SNP) | VAF 22/72 reads (31%) | catalogued as COSV99740017; called by muse, mutect2, varscan2
- ELL2 | c.1405_1411del p.H469Kfs*5 | Frame Shift Del (DEL) | VAF 40/201 reads (20%) | called by pindel, varscan2
- HSD17B4 | c.1648+1del | Frame Shift Del (DEL) | VAF 62/231 reads (27%) | called by mutect2, pindel, varscan2
- KMT2C | c.13729_13730del p.P4577Cfs*4 | Frame Shift Del (DEL) | VAF 27/91 reads (30%) | called by mutect2, pindel, varscan2
- CACNA1C | c.1158C>T p.V386= | Silent (SNP) | VAF 31/578 reads (5%) | catalogued as COSV100220046; called by muse, mutect2
- CAMSAP1 | c.2196T>A p.T732= | Silent (SNP) | VAF 30/98 reads (31%) | catalogued as COSV56726892; called by muse, mutect2, varscan2
- H2AC20 | c.342C>G p.A114= | Silent (SNP) | VAF 23/124 reads (19%) | catalogued as COSV58612934; called by muse, mutect2, varscan2
- KCTD20 | c.429G>A p.L143= | Silent (SNP) | VAF 9/147 reads (6%) | catalogued as COSV54803992; called by muse, mutect2
- NCR2 | c.333C>A p.I111= | Silent (SNP) | VAF 27/78 reads (35%) | catalogued as COSV100897230, COSV66101156; called by muse, mutect2, varscan2
- RTN4RL1 | c.1263G>A p.S421= | Silent (SNP) | VAF 12/18 reads (67%) | catalogued as rs750018121, COSV58677432; called by muse, mutect2, varscan2
- SHARPIN | c.906T>G p.A302= | Silent (SNP) | VAF 13/49 reads (27%) | catalogued as COSV59644919; called by muse, mutect2, varscan2
